Somatic mutation profile of tumor specimen ALCH-B1WC-TTP1-A (aliquot ALCH-B1WC-TTP1-A-1-0-D-A771-36) from ALCHEMIST case ALCH-B1WC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.2 years (26,381 days).
Specimen ALCH-B1WC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cfe09dd-d6fe-4ce0-b560-102a17b980d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1WC-NB1-A (Blood Derived Normal), aliquot ALCH-B1WC-NB1-A-1-0-D-A771-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8664e40b-5b74-4196-a796-380ff2747c7f

The open-access MAF lists 174 somatic variants for this specimen: 133 protein-altering or splice-affecting, 27 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 27, Nonsense Mutation 12, Intron 10, Splice Region 3, RNA 2, Translation Start Site 2, Splice Site 1, 5'UTR 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 66/796 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABI3BP | c.1274C>A p.T425K | Missense Mutation (SNP) | VAF 52/599 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52549787; called by muse, mutect2
- ADCY2 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV57897918; called by muse, mutect2
- AGGF1 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 50/1140 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs909784085; called by muse, mutect2
- AMER1 | c.1968G>T p.M656I | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57669085; called by muse, mutect2
- CEP152 | c.4576G>T p.D1526Y (on ENST00000380950 / NM_001194998.2; = p.D1470Y on NM_014985.4) | Missense Mutation (SNP) | VAF 52/886 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV57856542; called by muse, mutect2
- CNTNAP2 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 59/874 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.569); catalogued as rs992707860; called by muse, mutect2
- COL12A1 | c.6941G>T p.R2314L | Missense Mutation (SNP) | VAF 46/854 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.019); catalogued as COSV100486658; called by muse, mutect2
- DEFB113 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 21/466 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV59038669; called by muse, mutect2
- EPHA3 | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.891); catalogued as COSV60692802; called by muse, mutect2, varscan2
- EPHA3 | c.1133C>A p.P378Q | Missense Mutation (SNP) | VAF 64/780 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV60697000; called by muse, mutect2
- FAM47C | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 24/387 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs782732673; called by muse, mutect2
- FAT2 | c.4973C>A p.P1658H | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55821435; called by muse, mutect2
- FBN3 | c.8306G>T p.G2769V | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53664075, COSV53665308; called by muse, mutect2
- FGF13 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV65432871; called by muse, mutect2
- GHSR | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as COSV53841005; called by muse, mutect2, varscan2
- GPR31 | c.788C>A p.T263N | Missense Mutation (SNP) | VAF 28/391 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV64761313; called by muse, mutect2
- HAO2 | c.36T>A p.H12Q | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs770886338; called by muse, mutect2
- HS3ST1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1198508216; called by muse, mutect2
- IGKV2D-24 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs773129819; called by muse, mutect2
- NLRP3 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV100275435; called by muse, mutect2
- NPAP1 | c.3045G>T p.M1015I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100275640, COSV61505254; called by muse, mutect2
- OR5W2 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as COSV60615576; called by muse, mutect2
- PCDHB16 | c.1858C>A p.H620N | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53372691; called by muse, mutect2
- PLCB1 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 32/609 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100568919; called by muse, mutect2
- PPFIA2 | c.762G>C p.K254N | Missense Mutation (SNP) | VAF 25/367 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV61019056; called by muse, mutect2
- RIF1 | c.4006G>C p.E1336Q | Missense Mutation (SNP) | VAF 20/625 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as COSV54625415; called by muse, mutect2
- RSF1 | c.3474G>T p.Q1158H | Missense Mutation (SNP) | VAF 23/457 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV57846135; called by muse, mutect2
- RYR2 | c.12626C>T p.S4209L | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as COSV100771897; called by muse, mutect2
- SLC5A1 | c.375G>T p.V125= | Splice Region (SNP) | VAF 36/550 reads (7%) | catalogued as rs1322566407, COSV99833365; called by muse, mutect2
- SLCO6A1 | c.1815-7C>T | Splice Region (SNP) | VAF 28/450 reads (6%) | catalogued as rs757253193; called by muse, mutect2
- SOX5 | c.1917G>T p.K639N | Missense Mutation (SNP) | VAF 48/839 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV58632957; called by muse, mutect2
- TM4SF18 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs774838430; called by muse, mutect2
- TRMT2B | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.191); catalogued as rs1451795356; called by muse, mutect2, varscan2
- VPS13C | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 22/644 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV51137770; called by muse, mutect2
- ZNF354A | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV59984325; called by muse, mutect2
- ZNF365 | c.32A>T p.Y11F | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.049); catalogued as COSV67925164; called by muse, mutect2
- ADGRG2 | c.2783C>T p.S928L (on ENST00000379869 / NM_001079858.3; = p.S925L on NM_005756.4) | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADRA2C | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AFF2 | c.456C>A p.N152K | Missense Mutation (SNP) | VAF 31/568 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- AMIGO2 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 10/287 reads (3%) | called by muse, mutect2
- ARMCX5 | c.1412G>T p.S471I | Missense Mutation (SNP) | VAF 23/307 reads (7%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.977); called by muse, mutect2
- BCORL1 | c.1508C>G p.P503R | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BDP1 | c.7286C>A p.T2429K | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); called by muse, mutect2
- BRDT | c.2652C>A p.C884* | Nonsense Mutation (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- C3orf20 | c.2155C>A p.Q719K | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, varscan2
- CABYR | c.829C>G p.P277A | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2
- CADM2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 19/229 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); called by muse, mutect2
- CARD6 | c.1793G>T p.R598M | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2
- CHM | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 42/842 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CNDP2 | c.633G>T p.R211S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTNAP1 | c.1952A>T p.Y651F | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- CPB1 | c.715A>T p.T239S | Missense Mutation (SNP) | VAF 68/1187 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- CSNK1A1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- DCAF11 | c.564G>T p.M188I | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- DDX39A | c.667T>C p.C223R | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2
- DISP1 | c.4164G>T p.M1388I | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- DKC1 | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 61/864 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DNM3 | c.2290C>T p.Q764* (on ENST00000355305 / NM_001350206.2; = p.Q758* on NM_015569.5) | Nonsense Mutation (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- DPP6 | c.457+3G>C | Splice Region (SNP) | VAF 39/476 reads (8%) | called by muse, mutect2
- DUSP16 | c.328A>T p.K110* | Nonsense Mutation (SNP) | VAF 32/492 reads (7%) | called by muse, mutect2
- EIF4E1B | c.216C>A p.F72L | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2
- EVC | c.1814A>T p.Q605L | Missense Mutation (SNP) | VAF 32/548 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); called by muse, mutect2
- FAM149A | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- FAM47C | c.278G>T p.R93M | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2
- FBN2 | c.8290G>T p.E2764* | Nonsense Mutation (SNP) | VAF 42/734 reads (6%) | called by muse, mutect2
- FKBP15 | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 39/459 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2
- FNDC1 | c.4751C>A p.T1584K | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.432); called by muse, mutect2
- FRMPD1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 37/532 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- GSAP | c.1306T>G p.C436G | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.215); called by muse, mutect2
- HCK | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- HTT | c.3921G>T p.M1307I | Missense Mutation (SNP) | VAF 38/621 reads (6%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.921); called by muse, mutect2
- IGLV2-11 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 19/317 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.048); called by muse, mutect2
- IGSF1 | c.1713C>A p.C571* | Nonsense Mutation (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- INTS6L | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- IPO8 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 17/323 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by muse, mutect2
- KALRN | c.5461A>G p.K1821E (on ENST00000360013 / NM_001024660.4; = p.K124E on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.615); called by muse, mutect2
- KLHL14 | c.1858C>G p.L620V | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2
- KMT2C | c.6029C>T p.P2010L | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- LPXN | c.524A>C p.H175P | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEA10 | c.927G>T p.M309I | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2
- MSMO1 | c.803G>A p.W268* | Nonsense Mutation (SNP) | VAF 18/431 reads (4%) | called by muse, mutect2
- MTERF3 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 61/533 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- NAIF1 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- NAPB | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 38/558 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2
- NELL2 | c.1369T>C p.C457R | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- NME5 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- NPAS3 | c.906G>T p.R302S (on ENST00000356141 / NM_001164749.2; = p.R270S on NM_022123.3) | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2
- NRXN3 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OCA2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 24/248 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- PCDH15 | c.4372T>C p.F1458L | Missense Mutation (SNP) | VAF 34/778 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2
- PCDHA1 | c.1288G>T p.G430W | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2
- PCDHB11 | c.507C>A p.S169R | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2
- PCDHGA5 | c.1808G>T p.W603L | Missense Mutation (SNP) | VAF 18/335 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PDE1C | c.2057G>T p.R686M | Missense Mutation (SNP) | VAF 10/314 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); called by muse, mutect2
- PKD1 | c.5666G>T p.G1889V | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PLCE1 | c.5231C>T p.S1744F | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEC | c.7839G>T p.M2613I (on ENST00000322810 / NM_201380.4; = p.M2503I on NM_000445.5) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); called by muse, mutect2
- PRDM14 | c.1626G>T p.E542D | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- PRKG2 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 23/628 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- RAPH1 | c.3434C>A p.A1145D | Missense Mutation (SNP) | VAF 32/341 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); called by muse, mutect2
- RELN | c.862A>T p.K288* | Nonsense Mutation (SNP) | VAF 60/1148 reads (5%) | called by muse, mutect2
- RNF40 | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.027); called by muse, mutect2
- ROBO3 | c.1856T>A p.L619Q | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RTL9 | c.1943C>T p.T648I | Missense Mutation (SNP) | VAF 15/368 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2
- RUNX1T1 | c.178C>A p.P60T (on ENST00000265814 / NM_001198628.1; = p.P33T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- SCN1A | c.2618G>T p.W873L (on ENST00000303395 / NM_001202435.3; = p.W862L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- SCN3B | c.46A>T p.I16F | Missense Mutation (SNP) | VAF 21/426 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- SLC29A3 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC35G3 | c.476G>T p.W159L | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC4A4 | c.930G>A p.M310I (on ENST00000264485 / NM_001098484.3; = p.M266I on NM_003759.4) | Missense Mutation (SNP) | VAF 38/577 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.209); called by muse, mutect2
- SLITRK2 | c.831T>A p.H277Q | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- SLITRK5 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 26/449 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SMC1B | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 34/620 reads (5%) | called by muse, mutect2
- SP3 | c.2308C>G p.Q770E | Missense Mutation (SNP) | VAF 24/607 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- SPINK5 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 48/984 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- TARS1 | c.984G>C p.R328S | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2
- TBL1XR1 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 32/675 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2
- TBL3 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.926); called by muse, mutect2
- TEAD4 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 12/243 reads (5%) | called by muse, mutect2
- TENM4 | c.2159C>G p.T720S | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.97); called by muse, mutect2
- TET1 | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- TEX11 | c.1291C>T p.Q431* (on ENST00000344304; = p.Q416* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- THUMPD2 | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- TNS3 | c.1538A>T p.H513L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- TRRAP | c.8267A>T p.Q2756L (on ENST00000359863 / NM_001244580.1; = p.Q2738L on NM_003496.3) | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UACA | c.147A>T p.K49N | Missense Mutation (SNP) | VAF 29/808 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP49 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZIM3 | c.1181A>T p.N394I | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.648); called by muse, mutect2
- ZNF211 | c.773A>T p.E258V (on ENST00000347302 / NM_198855.4; = p.E271V on NM_006385.5) | Missense Mutation (SNP) | VAF 42/632 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2
- ZNF451 | c.703-1G>T p.X235_splice | Splice Site (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- ZNF512B | c.960del p.C321Afs*6 | Frame Shift Del (DEL) | VAF 18/158 reads (11%) | called by mutect2, pindel, varscan2
- ZNF75D | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2
- ADGRL3 | c.4548C>G p.A1516= (on ENST00000506720 / NM_001322402.2; = p.A1405= on NM_015236.6) | Silent (SNP) | VAF 28/410 reads (7%) | called by muse, mutect2
- AGBL1 | c.2466C>A p.V822= | Silent (SNP) | VAF 11/264 reads (4%) | catalogued as rs1329411965, COSV66855151; called by muse, mutect2
- ATG3 | c.450T>C p.D150= | Silent (SNP) | VAF 30/594 reads (5%) | called by muse, mutect2
- C9orf85 | c.348G>A p.R116= | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- DISP3 | c.3669G>A p.V1223= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV53835370; called by muse, mutect2
- DNAH17 | c.8605C>T p.L2869= | Silent (SNP) | VAF 16/274 reads (6%) | catalogued as rs1447700283, COSV67758013; called by muse, mutect2
- DOCK5 | c.2878C>T p.L960= | Silent (SNP) | VAF 26/444 reads (6%) | called by muse, mutect2
- FAM47C | c.277A>C p.R93= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- FBN2 | c.3369T>A p.P1123= | Silent (SNP) | VAF 54/679 reads (8%) | catalogued as rs758977496, COSV52492270; called by muse, mutect2
- FLG | c.4828C>A p.R1610= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as rs560805546, COSV64238918; called by muse, mutect2
- IGHD6-25 | c.18C>T p.Y6= | Silent (SNP) | VAF 10/217 reads (5%) | catalogued as rs781946821; called by muse, mutect2
- IL1RAP | c.942G>A p.Q314= | Silent (SNP) | VAF 178/494 reads (36%) | called by muse, mutect2, varscan2
- MUC16 | c.8166C>A p.L2722= | Silent (SNP) | VAF 13/147 reads (9%) | catalogued as rs370245414; called by muse, mutect2
- OR5B17 | c.54C>A p.A18= | Silent (SNP) | VAF 15/206 reads (7%) | catalogued as COSV62161263; called by muse, mutect2
- PABPC1 | c.630C>G p.L210= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as rs747125011; called by muse, mutect2
- PRDM9 | c.420G>T p.L140= | Silent (SNP) | VAF 45/446 reads (10%) | catalogued as COSV99690700, COSV99690727; called by muse, mutect2, varscan2
- PTPN22 | c.360T>C p.Y120= | Silent (SNP) | VAF 18/254 reads (7%) | called by muse, mutect2
- SCUBE1 | c.1464C>A p.A488= | Silent (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- TBC1D23 | c.1140G>A p.L380= | Silent (SNP) | VAF 42/802 reads (5%) | called by muse, mutect2
- TRIM77 | c.168G>A p.R56= | Silent (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- TTC8 | c.1509T>A p.A503= (on ENST00000338104 / NM_001288781.1; = p.A487= on NM_144596.4) | Silent (SNP) | VAF 28/992 reads (3%) | called by muse, mutect2
- ULK2 | c.2079T>C p.N693= | Silent (SNP) | VAF 50/656 reads (8%) | called by muse, mutect2
- URB1 | c.2367G>T p.A789= | Silent (SNP) | VAF 13/187 reads (7%) | called by muse, mutect2
- USP49 | c.327G>T p.T109= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- ZNF396 | c.291G>T p.L97= | Silent (SNP) | VAF 20/419 reads (5%) | catalogued as rs912303227; called by muse, mutect2
- ZNF570 | c.1191G>A p.Q397= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as rs1408511743; called by muse, mutect2
- ZNF679 | c.375A>G p.V125= | Silent (SNP) | VAF 50/880 reads (6%) | called by muse, mutect2
- ANK2 | c.3380-18G>C | Intron (SNP) | VAF 38/864 reads (4%) | called by muse, mutect2
- ATP8B3 | c.2190+10G>T | Intron (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- CTNND1 | c.-180G>C | 5'UTR (SNP) | VAF 56/760 reads (7%) | called by muse, mutect2
- DIS3 | c.228+266G>A | Intron (SNP) | VAF 38/554 reads (7%) | called by muse, mutect2
- FGFR4 | c.1058-109T>A | Intron (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- GUSBP10 | n.293C>A | RNA (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- LGALS9C | c.761+39C>A | Intron (SNP) | VAF 15/189 reads (8%) | catalogued as rs763149107; called by muse, mutect2
- MED23 | c.3472-23C>T | Intron (SNP) | VAF 34/538 reads (6%) | called by muse, mutect2
- MED23 | c.3472-24A>T | Intron (SNP) | VAF 34/535 reads (6%) | called by muse, mutect2
- NRIP1 | c.-537-7220C>T | Intron (SNP) | VAF 49/773 reads (6%) | catalogued as rs755055800; called by muse, mutect2
- OR2W5 | n.919G>T | RNA (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- PHF23 | c.34+418C>T | Intron (SNP) | VAF 23/292 reads (8%) | called by muse, mutect2
- TMEM255B | c.190-833G>T | Intron (SNP) | VAF 6/100 reads (6%) | catalogued as rs1210212637, COSV64704578; called by muse, mutect2
- XIAP | c.*270G>C | 3'UTR (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
